CCDI case PBCATH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/52fa57ee-d4af-42c8-b569-b3e53c66e0c2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.0 years (3,289 days).

Biospecimens (3 samples)
- Sample 0DMN1F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN28: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
